Somatic mutation profile of tumor specimen C3L-04475-01 (aliquot CPT0238820008) from CPTAC case C3L-04475, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.8 years (28,419 days).
Specimen C3L-04475-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17169cdb-4877-4a71-b375-5461c40c7d91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04475-31 (Blood Derived Normal), aliquot CPT0238860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4c5ccd8-6b5e-4a66-9fa2-ac83b8462de5

The open-access MAF lists 57 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Intron 3, RNA 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 46/496 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- AFP | c.550del p.R184Afs*5 | Frame Shift Del (DEL) | VAF 40/371 reads (11%) | catalogued as COSV56925328; called by mutect2, pindel, varscan2
- BMT2 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376187358; called by muse, mutect2, varscan2
- CYP46A1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs148568536; called by muse, mutect2, varscan2
- DCST2 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 68/618 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs200847364, COSV55051586; called by muse, mutect2, varscan2
- ENTPD6 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.443); catalogued as rs780480288; called by muse, mutect2
- ISX | c.106A>T p.I36F | Missense Mutation (SNP) | VAF 92/751 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58088022; called by mutect2, varscan2
- MYLK4 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as rs780360412; called by muse, mutect2, varscan2
- NALCN | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.793); catalogued as rs549926959, COSV51923120, COSV51930613; called by muse, mutect2
- NEFM | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 87/727 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as rs531889441, COSV55332080; called by muse, mutect2, varscan2
- NMS | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs183314287, COSV65259014; called by muse, mutect2
- PCSK9 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100135399, COSV56163865; called by muse, mutect2, varscan2
- PROKR2 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 97/874 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779869864, COSV54086366; called by muse, mutect2, varscan2
- RABL2A | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 36/636 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1404186835, COSV100905719; called by muse, mutect2
- RTL4 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs751946941, COSV61206268; called by muse, mutect2, varscan2
- SARS1 | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1161613259; called by muse, mutect2
- SLC1A6 | c.1450G>A p.G484S | Missense Mutation (SNP) | VAF 22/303 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770765624, COSV55669575; called by muse, mutect2
- SLC7A14 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 34/435 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774948709, COSV99200507; called by muse, mutect2
- SMYD5 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 47/489 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs373347931; called by muse, mutect2
- THY1 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 81/665 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1433963612; called by muse, mutect2, varscan2
- TNPO3 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as rs964315128; called by muse, mutect2, varscan2
- TP53 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 65/420 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM951232, COSV52837901, COSV52987484, COSV53189701, COSV53518652; called by muse, mutect2, varscan2
- TTC27 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 65/832 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs751228170; called by muse, mutect2
- TYK2 | c.2669C>T p.T890M | Missense Mutation (SNP) | VAF 54/590 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1303144673, COSV53384829; called by muse, mutect2
- ZFP37 | c.1640G>A p.C547Y | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903618259; called by muse, mutect2
- AP3D1 | c.3112T>A p.F1038I | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2
- APBA1 | c.1901T>A p.L634Q | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CCAR1 | c.1198_1200del p.T400del | In Frame Del (DEL) | VAF 29/307 reads (9%) | called by mutect2, pindel
- DALRD3 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP5 | c.451A>T p.I151F | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HCN1 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ2 | c.7511C>T p.T2504I (on ENST00000467148 / NM_001037335.2; = p.T1935I on NM_033405.3) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- HTR3E | c.725C>G p.A242G (on ENST00000415389 / NM_001256613.1; = p.A257G on NM_182589.2) | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LRRC47 | c.1050T>A p.N350K | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, varscan2
- RASGRF1 | c.2248T>C p.S750P | Missense Mutation (SNP) | VAF 31/367 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- SLC22A4 | c.520T>C p.F174L | Missense Mutation (SNP) | VAF 66/651 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- TEAD1 | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 72/626 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZFHX4 | c.1201A>G p.M401V | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF417 | c.783T>A p.D261E | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ARHGAP23 | c.1317G>T p.R439= | Silent (SNP) | VAF 69/768 reads (9%) | called by muse, mutect2
- DUSP10 | c.177G>A p.T59= | Silent (SNP) | VAF 39/326 reads (12%) | catalogued as rs754587624, COSV60458562; called by muse, mutect2, varscan2
- ENAM | c.2547T>A p.P849= | Silent (SNP) | VAF 78/709 reads (11%) | called by muse, mutect2, varscan2
- GRIA1 | c.333G>A p.P111= | Silent (SNP) | VAF 89/843 reads (11%) | catalogued as rs750448884, COSV53597890, COSV99603170; called by muse, mutect2, varscan2
- IGHV1-58 | c.213C>T p.V71= | Silent (SNP) | VAF 98/1042 reads (9%) | called by muse, mutect2
- ISX | c.105G>A p.A35= | Silent (SNP) | VAF 98/780 reads (13%) | catalogued as rs760200279, COSV100434153; called by muse, mutect2, varscan2
- MED12L | c.4218C>T p.S1406= | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as rs541572659, COSV56387292; called by muse, mutect2
- NGRN | c.42C>T p.C14= | Silent (SNP) | VAF 63/621 reads (10%) | catalogued as rs748216905; called by muse, mutect2, varscan2
- PCSK2 | c.1011C>T p.D337= | Silent (SNP) | VAF 77/825 reads (9%) | catalogued as rs1020319388; called by muse, mutect2
- PRDM9 | c.6C>T p.S2= | Silent (SNP) | VAF 79/763 reads (10%) | catalogued as rs752095846, COSV57014747; called by muse, mutect2, varscan2
- RBMXL3 | c.2274C>T p.D758= | Silent (SNP) | VAF 58/244 reads (24%) | catalogued as rs1326998928, COSV57750383; called by muse, mutect2, varscan2
- SLC41A1 | c.684C>G p.A228= | Silent (SNP) | VAF 78/697 reads (11%) | called by muse, mutect2, varscan2
- ZNF80 | c.270C>T p.V90= | Silent (SNP) | VAF 49/410 reads (12%) | catalogued as rs111785883; called by muse, mutect2, varscan2
- MKS1 | c.1274-29T>C | Intron (SNP) | VAF 52/406 reads (13%) | catalogued as rs370995006; called by muse, mutect2, varscan2
- OTOGL | c.6268-316_6268-297del | Intron (DEL) | VAF 23/149 reads (15%) | called by mutect2, pindel
- PKD1L2 | n.312C>T | RNA (SNP) | VAF 28/424 reads (7%) | called by muse, mutect2
- REXO1 | c.158-2124C>T | Intron (SNP) | VAF 6/15 reads (40%) | catalogued as rs1470227596, COSV50078247; called by muse, mutect2, varscan2
- RPS26P15 | n.57G>A | RNA (SNP) | VAF 61/640 reads (10%) | catalogued as rs781319989; called by muse, mutect2, varscan2
